Surgical pathology report (de-identified scan), TCGA case TCGA-B9-4115, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site UNC, specimen TCGA-B9-4115-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY

Surgical Pathology Report

Accession #:

Diagnosis:

Kidney, right, nephrectomy

Histologic tumor type/subtype: renal cell carcinoma,
papillary subtype

Histologic grade (if applicable): Fuhrman grade 3 (of 4)

Tumor size (greatest dimension): multifocal, largest tumor
nodule 4 cm in greatest dimension

Extent of tumor invasion:

Capsular invasion/perirenal adipose tissue: not identified

Gerota's fascia: not identified

Renal vein: not identified

Ureter: not identified

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Perirenal adipose tissue: negative for malignancy

Gerota's fascia: negative for malignancy

Renal vein: negative for malignancy

Renal artery: negative for malignancy

Ureter: negative for malignancy

Adrenal gland: not present

Lymph nodes: not identified

Other significant findings: mild glomerulo- and
arteriolonephrosclerosis with interstitial fibrosis with

[page 2 of 3]
focal chondrous metaplasia.

AJCC Staging:

pT1a

pNx

pMx

This staging information is based on information available at the time of this report, and is subject to change pending clinical review and additional information.

Clinical History:

with a bilateral renal mass.

Gross Description:

Specimen fixation: formalin

Type of specimen: nephrectomy, unspecified

Side of specimen: right

Size and weight of specimen: 950 grams; The specimen in its entirety is 24 x 15 x 6.5 cm. The kidney is 11.5 x 7 x 7 cm.

Orientation: The superficial surface surrounding the tumor is inked blue.

Presence/absence of adrenal gland: absent

Tumor description/site: There are multiple cortical tumor nodules. The largest is superior and midline. There are three other smaller tumor nodules scattered about the renal cortex. These nodules are mostly superior.

Tumor size: There are multiple tumor nodules present, the largest measures 4 x 3.8 x 3.0 cm. The second largest measures 3.5 x 2.8 x 2.0 cm. Multiple smaller nodules are also found. These are scattered throughout the renal parenchyma.

Presence/absence of multicentricity: present, at least 6

Confinement/non-confinement to the kidney: Extending through the renal capsule.

[page 3 of 3]
Extent of invasion:

Perirenal adipose tissue: tumor grossly involves
Gerota' s fascia: not present
Renal vein: does not involve
Ureter: does not involve
Other organs: n/a

Surgical margins:

Perirenal adipose tissue: positive
Renal vein: negative
Renal artery: negative
Ureter: negative

Description of kidney away from tumor: The kidney is pink/brown. There is a distinct corticomedullary junction. The cortex measures approximately 0.9 cm while the medulla measures approximately 1.2 cm.

Lymph nodes (hilar): The hilar area is palpated and no lymph nodes are found.

Other significant findings: none

Tissue submitted for special investigations: tumor and normal are submitted to Tissue Procurement

Digital photograph taken: not taken

Block summary:

- A1 - vascular, ureteral margins
- A2 - tumor extending out of capsule
- A3 - tumor extending out of capsule in area of renal sinus
- A4 - tumor with adjacent normal tissue
- A5 - perinephric fat firmly adherent to tumor
- A6 - additional tumor adherent to perinephric fat with blue ink margin
- A7 - tumor nodule
- A8 - separate tumor nodule
- A9 - tumor from largest nodule
- A10 - perirenal fat
- A11 - separate tumor nodule
- A12 - normal kidney
- A13 - hilar fat adjacent to hilar structures
- A14 - tumor at hilum

Source: NCI Genomic Data Commons file b907a63a-7957-4104-9dc0-1a5cd7a53985 (TCGA-B9-4115.4B43E168-B59E-4A34-908B-26F95A44B712.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).